TCGA case TCGA-AF-A56K — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectosigmoid junction; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bd818ae4-b31a-4616-9303-b8aee56a848f

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C19; Tissue or organ of origin: Rectosigmoid junction; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 56.2 years (20,527 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,635 days (7.2 years).
   Pathology details: Circumferential resection margin: 0; Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 44; Lymphatic invasion present: No; Non nodal tumor deposits: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 59.5 years (21,744 days); Days to diagnosis: 1,217 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,458 days (4.0 years); Residual disease: R1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 1,217 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional.
- Days to follow up: 2,396 days (6.6 years); Disease response: Tumor Free.
- Days to follow up: 2,635 days (7.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 0.5 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 145.5 kg; Height: 182.5 cm; BMI: 43.7.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AF-A56K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 360 mg.
  Slide TCGA-AF-A56K-01A-03-TS3: Section location: Top; Percent tumor cells: 97; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-AF-A56K-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AF-A56K-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Rectum; Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 0.5; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- New tumor event: New tumor event type: Locoregional Disease; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,635 days; disease-specific survival: no event (censored), 2,635 days; disease-free interval: event (new tumor event after initially disease-free), 1,217 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,217 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AF-A56K-01A-32D-A38W-01): tumor purity 0.55, ploidy 3.34, whole-genome doublings 1.
